Somatic mutation profile of tumor specimen TCGA-BR-8363-01A (aliquot TCGA-BR-8363-01A-11D-2340-08) from TCGA case TCGA-BR-8363, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.9 years (26,976 days).
Specimen TCGA-BR-8363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd06ca0d-a6d2-4645-a3b2-f1a807405b15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8363-10A (Blood Derived Normal), aliquot TCGA-BR-8363-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06584686-1efc-44a1-9b63-f99a05375dad

The open-access MAF lists 1,467 somatic variants for this specimen: 1,130 protein-altering or splice-affecting, 303 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 771, Silent 303, Frame Shift Del 256, Frame Shift Ins 39, Nonsense Mutation 33, Intron 21, In Frame Del 10, Splice Site 10, Splice Region 7, RNA 5, 5'Flank 4, Nonstop Mutation 4.

Variants (750 of 1,467; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSA | c.418del p.H140Ifs*8 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs745884435, CD085806, CM085251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- ATM | c.640del p.S214Pfs*16 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs786204543; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- COL4A5 | c.1376del p.P459Qfs*15 | Frame Shift Del (DEL) | VAF 43/321 reads (13%) | catalogued as rs104886113, CD961911; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 8/45 reads (18%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- EIF2B5 | c.1054C>T p.R352* (on ENST00000647909; = p.R344* on NM_003907.3) | Nonsense Mutation (SNP) | VAF 31/191 reads (16%) | catalogued as rs1560108537, COSV56605054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.2321G>A p.S774N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV61503462; called by muse, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 37/194 reads (19%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1966del p.L656Cfs*274 | Frame Shift Del (DEL) | VAF 44/173 reads (25%) | catalogued as rs886042284; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LTBP3 | c.2216del p.G739Afs*7 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as rs752375653, CD153951; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH2 | c.687del p.A230Lfs*16 | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | catalogued as rs63749897; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHP4 | c.4075C>T p.R1359W | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as rs369162678; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PTCH1 | c.290del p.N97Tfs*20 | Frame Shift Del (DEL) | VAF 18/115 reads (16%) | catalogued as rs1554708751, CD066395, CX962597; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- SMARCA4 | c.2343G>T p.M781I | Missense Mutation (SNP) | VAF 13/118 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60787487, COSV60798909, COSV60801851; called by muse, mutect2, varscan2
- TPP1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs121908209, CM024342, COSV54994722; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- TRIM37 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as rs386834001, CM041087, COSV51886163; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.6337A>G p.R2113G | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242275070, COSV66068243; called by muse, mutect2, varscan2
- ABCA13 | c.7613C>A p.T2538K | Missense Mutation (SNP) | VAF 52/330 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV71291242; called by muse, mutect2, varscan2
- ABCB5 | c.3080G>A p.R1027H (on ENST00000404938 / NM_001163941.2; = p.R582H on NM_178559.6) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs745749100, COSV51703658, COSV51718688; called by muse, mutect2, varscan2
- ABCG2 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV52947447; called by muse, mutect2, varscan2
- ACAA1 | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs751301935, COSV57176976; called by muse, mutect2, varscan2
- ACACB | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs78715638, COSV58130354, COSV58143525, COSV58144420; called by muse, mutect2
- ACACB | c.5666C>T p.S1889F | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100622823; called by muse, mutect2, varscan2
- ACAD10 | c.833T>A p.L278Q | Missense Mutation (SNP) | VAF 54/361 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58159505; called by muse, mutect2, varscan2
- ACAD8 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV55541387; called by muse, mutect2, varscan2
- ACBD7 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV100650440; called by muse, mutect2, varscan2
- ACSS3 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446264332, COSV54095776; called by muse, mutect2
- ACTRT3 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs1319423036, COSV57754798; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 36/155 reads (23%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 26/166 reads (16%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS13 | c.3614T>C p.M1205T | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV52470891; called by muse, mutect2, varscan2
- ADAMTS16 | c.2276A>G p.N759S | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as COSV56997474, COSV99939882; called by muse, mutect2, varscan2
- ADAMTS18 | c.3520A>G p.T1174A | Missense Mutation (SNP) | VAF 44/391 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV51419034; called by muse, mutect2, varscan2
- ADAMTS18 | c.2475C>A p.F825L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs756053041, COSV51419040; called by muse, mutect2, varscan2
- ADGRF1 | c.1849del p.S617Afs*12 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | catalogued as rs1344904964; called by mutect2, pindel, varscan2
- ADGRG2 | c.436A>G p.T146A (on ENST00000379869 / NM_001079858.3; = p.T143A on NM_005756.4) | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.387); catalogued as COSV61340151; called by muse, mutect2, varscan2
- ADGRG4 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as rs780690525, COSV54961493; called by muse, mutect2, varscan2
- ADGRG4 | c.2752A>C p.T918P | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV54961505; called by muse, mutect2, varscan2
- ADGRG4 | c.5605A>G p.R1869G | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54961513, COSV99794566; called by muse, mutect2, varscan2
- AFF1 | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV57121815, COSV57124564; called by muse, mutect2, varscan2
- AGAP1 | c.2240C>T p.T747M (on ENST00000304032 / NM_001037131.3; = p.T694M on NM_014914.5) | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.843); catalogued as COSV58332456; called by muse, mutect2, varscan2
- AGTR1 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62559040; called by muse, mutect2, varscan2
- AHCTF1 | c.1562G>A p.G521E (on ENST00000366508; = p.G495E on NM_015446.5) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as COSV58252438; called by muse, mutect2, varscan2
- AIFM3 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV59001291; called by muse, mutect2, varscan2
- ALDH16A1 | c.1039del p.A347Lfs*155 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as rs1368010977; called by mutect2, pindel, varscan2
- ALDOC | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52025469; called by muse, mutect2, varscan2
- ALKBH5 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315958769, COSV67687169; called by muse, mutect2, varscan2
- AMIGO1 | c.1200C>A p.C400* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV63990489; called by muse, mutect2, varscan2
- AMMECR1 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53318934; called by muse, mutect2, varscan2
- AMPD3 | c.299del p.P100Rfs*60 (on ENST00000396553 / NM_001025389.2; = p.P109Rfs*60 on NM_000480.3) | Frame Shift Del (DEL) | VAF 60/457 reads (13%) | catalogued as rs751130603; called by mutect2, varscan2
- AMT | c.53T>C p.F18S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56470280; called by muse, mutect2, varscan2
- ANAPC1 | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV61977594; called by muse, mutect2, varscan2
- ANGPTL2 | c.1447A>G p.M483V | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV52220827; called by muse, mutect2, varscan2
- ANK2 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52173519, COSV52186719; called by muse, mutect2, varscan2
- ANK2 | c.5062C>T p.Q1688* | Nonsense Mutation (SNP) | VAF 13/133 reads (10%) | catalogued as COSV52173537; called by muse, mutect2, varscan2
- ANK3 | c.3728G>A p.R1243H (on ENST00000280772 / NM_001320874.2; = p.R377H on NM_001149.3) | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767721464, COSV55068508; called by muse, mutect2, varscan2
- ANKEF1 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as rs200572571, COSV65692858; called by muse, mutect2, varscan2
- ANKLE1 | c.738C>A p.S246R (on ENST00000394458; = p.S192R on NM_152363.6) | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV63921183; called by muse, mutect2, varscan2
- ANKRD33 | c.571G>A p.A191T (on ENST00000340970 / NM_001304459.2; = p.A316T on NM_182608.4) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.703); catalogued as COSV100001045, COSV56607292; called by muse, mutect2, varscan2
- ANO1 | c.2706G>A p.M902I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs1300562496, COSV62447547; called by muse, mutect2
- ANO4 | c.2135A>G p.E712G (on ENST00000392977 / NM_001286615.2; = p.E677G on NM_178826.4) | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54603924; called by muse, mutect2, varscan2
- AP1B1 | c.899A>G p.Y300C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780834015, COSV58020381; called by muse, mutect2, varscan2
- APBB3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 53/388 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs200163093, COSV60053252; called by muse, mutect2, varscan2
- APC | c.6920C>T p.S2307L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs901983934, COSV57330138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.3587A>C p.D1196A | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV51943215; called by muse, mutect2, varscan2
- APPBP2 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 68/378 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.706); catalogued as rs761525267, COSV50027935; called by muse, mutect2, varscan2
- ARFGEF1 | c.3449T>C p.V1150A | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV51602641; called by muse, varscan2
- ARGLU1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs764497745, COSV62271743; called by muse, mutect2, varscan2
- ARHGAP12 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777110210, COSV60964694; called by muse, mutect2, varscan2
- ARHGDIA | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV53907323; called by muse, mutect2, varscan2
- ARHGEF15 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs760515669, COSV100730115, COSV62725788; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.50del p.K17Rfs*21 | Frame Shift Del (DEL) | VAF 28/176 reads (16%) | catalogued as rs1290336606; called by mutect2, varscan2
- ARPC2 | c.241G>T p.G81W | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV55285636; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs753865255; called by mutect2, varscan2
- ARVCF | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459734964, COSV54268261; called by muse, mutect2, varscan2
- ASB1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.904); catalogued as rs146985743; called by muse, mutect2, varscan2
- ASCL1 | c.322T>G p.F108V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV57152110; called by muse, mutect2, varscan2
- ASCL4 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV60816968; called by muse, mutect2, varscan2
- ASPN | c.201del p.P68Hfs*24 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | catalogued as rs778526424; called by mutect2, pindel, varscan2
- ASXL1 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV60113665; called by muse, mutect2, varscan2
- ATP2B4 | c.491T>A p.L164* | Nonsense Mutation (SNP) | VAF 35/242 reads (14%) | catalogued as COSV58180375; called by muse, mutect2, varscan2
- ATP8B3 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.136); catalogued as COSV59545387; called by muse, mutect2, varscan2
- ATRX | c.3881A>G p.D1294G | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as rs1346512782, COSV64879810; called by muse, mutect2, varscan2
- B3GALT4 | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65851902; called by muse, mutect2, varscan2
- B3GNT6 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62828372; called by muse, mutect2, varscan2
- B4GALT4 | c.487-1G>T p.X163_splice | Splice Site (SNP) | VAF 10/55 reads (18%) | catalogued as COSV63296136; called by muse, mutect2, varscan2
- BACH1 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs906193032, COSV54519833, COSV54519879; called by muse, mutect2, varscan2
- BAHD1 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.727); catalogued as rs757855963, COSV69084256; called by muse, mutect2, varscan2
- BAIAP3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.286); catalogued as rs115052205, COSV60977511; called by muse, mutect2, varscan2
- BCL11A | c.1043G>A p.C348Y (on ENST00000335712 / NM_001365609.1; = p.C382Y on NM_018014.4) | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59633533; called by muse, mutect2, varscan2
- BCL6 | c.1123T>C p.W375R | Missense Mutation (SNP) | VAF 99/621 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51653868; called by muse, mutect2, varscan2
- BIRC6 | c.4834G>A p.A1612T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV70202662; called by muse, mutect2, varscan2
- BIRC7 | c.389del p.G130Afs*233 (on ENST00000217169 / NM_139317.3; = p.G130Afs*215 on NM_022161.4) | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | catalogued as COSV99416895; called by mutect2, pindel, varscan2
- BLM | c.298_299del p.Q100Efs*42 | Frame Shift Del (DEL) | VAF 24/131 reads (18%) | catalogued as rs745807085; called by pindel, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BPNT1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs753054605, COSV59040605; called by muse, mutect2, varscan2
- BPTF | c.5594A>G p.E1865G | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58841432; called by muse, mutect2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | catalogued as COSV56263190; called by mutect2, varscan2
- BRAP | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 73/238 reads (31%) | catalogued as rs756238292, COSV58159494; called by muse, mutect2, varscan2
- BSCL2 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs760470794, COSV54016668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD2 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs747021203, COSV55308114; called by muse, mutect2, varscan2
- BTN3A2 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs373600244; called by muse, mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 21/155 reads (14%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C12orf66 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61323902; called by muse, mutect2, varscan2
- C1QTNF9 | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 27/378 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.398); catalogued as rs755673923, COSV59657604; called by muse, mutect2
- C1S | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.057); catalogued as rs782616996, COSV61071423; called by muse, mutect2, varscan2
- C1orf127 | c.1663A>G p.K555E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV65437983; called by muse, mutect2, varscan2
- C20orf96 | c.439C>A p.L147M (on ENST00000360321 / NM_153269.3; = p.L146M on NM_080571.1) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV64404000; called by muse, mutect2, varscan2
- C3 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.047); catalogued as COSV55576404; called by muse, mutect2, varscan2
- C3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as COSV55576417; called by muse, mutect2, varscan2
- CABYR | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.08); catalogued as rs542946323, COSV59111744; called by muse, mutect2, varscan2
- CACNA1A | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773414013, COSV64199244; called by muse, mutect2, varscan2
- CACNA1C | c.2846C>T p.A949V | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59743010; called by muse, mutect2, varscan2
- CACNA1C | c.3119A>C p.Q1040P | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59743034; called by muse, mutect2, varscan2
- CACNG5 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV50057086; called by muse, mutect2, varscan2
- CADM1 | c.769A>C p.T257P | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59016209; called by muse, mutect2, varscan2
- CARD14 | c.2747T>C p.M916T | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1351049921, COSV58339836; called by muse, mutect2, varscan2
- CARD8 | c.844G>C p.A282P (on ENST00000651546 / NM_001184900.3; = p.A232P on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV62874329, COSV62875022; called by muse, mutect2, varscan2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/138 reads (17%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CASP7 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61882434; called by muse, mutect2
- CASP8AP2 | c.2873G>A p.R958K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV52748425; called by muse, varscan2
- CAT | c.1000T>G p.F334V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV53812124; called by muse, mutect2, varscan2
- CAVIN1 | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63812322; called by muse, mutect2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 38/318 reads (12%) | catalogued as rs780649799; called by mutect2, varscan2
- CC2D1A | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375346936; called by muse, mutect2, varscan2
- CCDC144A | c.1159G>C p.V387L | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60699938; called by muse, mutect2, varscan2
- CCDC146 | c.2650G>A p.A884T | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs374451225; called by muse, mutect2, varscan2
- CCDC15 | c.2456G>A p.R819K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as rs1281680092, COSV61083273; called by muse, mutect2
- CCDC158 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs767021802, COSV101187340, COSV66356006; called by muse, mutect2, varscan2
- CCDC170 | c.2089A>G p.K697E | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV53343234; called by muse, mutect2, varscan2
- CCDC185 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs532620296, COSV64821330; called by muse, mutect2, varscan2
- CCDC7 | c.3080A>G p.Q1027R | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV56546816; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs762553129; called by mutect2, varscan2
- CCKAR | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.336); catalogued as COSV55162531; called by muse, mutect2, varscan2
- CCZ1B | c.1370del p.N457Mfs*4 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs777044936; called by mutect2, varscan2
- CD1A | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | catalogued as COSV56862576; called by muse, mutect2, varscan2
- CD58 | c.179del p.K60Rfs*24 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | catalogued as COSV65664776; called by mutect2, pindel, varscan2
- CD69 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1193168544, COSV57302501, COSV57303192; called by muse, mutect2, varscan2
- CDC27 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745491637, COSV50374936; called by muse, mutect2, varscan2
- CDH12 | c.1061A>G p.H354R | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.409); catalogued as COSV66423766; called by muse, mutect2, varscan2
- CDH15 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773680931, COSV57025741; called by muse, mutect2, varscan2
- CDH20 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.894); catalogued as rs767997572, COSV53013491; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs749612238, COSV62576141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEACAM3 | c.241G>T p.G81* | Nonsense Mutation (SNP) | VAF 61/356 reads (17%) | catalogued as COSV55762317, COSV55763601; called by muse, mutect2, varscan2
- CELA2B | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV65545914; called by muse, mutect2, varscan2
- CELSR2 | c.2584G>A p.G862S | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370447679; called by muse, mutect2, varscan2
- CELSR3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50842163; called by muse, mutect2, varscan2
- CENPB | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as COSV60148282; called by muse, mutect2, varscan2
- CEP128 | c.3239T>C p.M1080T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55383172; called by muse, mutect2
- CEP170 | c.3589T>A p.F1197I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100317656; called by mutect2, varscan2
- CEP68 | c.2054T>C p.V685A | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53126053; called by muse, mutect2, varscan2
- CEP89 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs141423846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 6/42 reads (14%) | catalogued as rs768479535; called by mutect2, pindel
- CFAP20DC | c.2061A>C p.E687D (on ENST00000482387 / NM_001351530.2; = p.E436D on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV55923447; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 31/161 reads (19%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP91 | c.2049C>T p.S683= | Splice Region (SNP) | VAF 14/134 reads (10%) | catalogued as rs757327899, COSV56342600; called by muse, mutect2, varscan2
- CGN | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as rs149778114, COSV54972344; called by muse, mutect2, varscan2
- CHRNA2 | c.1253A>T p.E418V | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1453727330, COSV53556180; called by muse, mutect2, varscan2
- CHST1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57321613; called by muse, mutect2, varscan2
- CHST11 | c.781A>C p.T261P | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV57990850; called by muse, mutect2, varscan2
- CHTF18 | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV50101247; called by muse, mutect2, varscan2
- CHUK | c.2150T>G p.L717R | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV64918294; called by muse, mutect2, varscan2
- CIDEA | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57599187; called by muse, mutect2, varscan2
- CLCA4 | c.1558C>T p.L520F | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55369599; called by muse, mutect2, varscan2
- CLCN3 | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61627824; called by muse, mutect2, varscan2
- CLOCK | c.438+2T>C p.X146_splice | Splice Site (SNP) | VAF 14/102 reads (14%) | catalogued as COSV59403510; called by muse, varscan2
- CLRN3 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV64098771, COSV64098829; called by muse, mutect2, varscan2
- CLSTN1 | c.1108G>A p.A370T (on ENST00000377298 / NM_001009566.3; = p.A360T on NM_014944.4) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV63649296; called by muse, mutect2, varscan2
- CLUH | c.1331C>T p.A444V (on ENST00000435359; = p.A482V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70929427; called by muse, mutect2
- CLVS1 | c.920A>G p.H307R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.045); catalogued as COSV57978713; called by muse, varscan2
- CMTM1 | c.455C>T p.P152L (on ENST00000457188 / NM_181269.3; = p.P269L on NM_052999.4) | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.943); catalogued as rs1465062509, COSV51749163; called by muse, mutect2, varscan2
- CMYA5 | c.2845T>C p.S949P | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV71407498; called by muse, mutect2, varscan2
- CNDP1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750904832, COSV62593178, COSV62594471; called by muse, mutect2, varscan2
- CNGA2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780670790, COSV61705135; called by muse, mutect2, varscan2
- CNP | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV66368657; called by muse, mutect2, varscan2
- CNST | c.1561A>G p.I521V | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs541054674, COSV63622127; called by muse, mutect2, varscan2
- CNTN5 | c.1463A>C p.K488T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV54331281; called by muse, mutect2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 15/120 reads (13%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTN6 | c.2413G>C p.A805P | Missense Mutation (SNP) | VAF 67/371 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV63180030; called by muse, mutect2, varscan2
- CNTNAP1 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.186); catalogued as COSV52852294; called by muse, mutect2, varscan2
- CNTNAP5 | c.710G>T p.R237M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV70496805; called by muse, mutect2
- CNTRL | c.5405del p.K1802Sfs*9 | Frame Shift Del (DEL) | VAF 21/125 reads (17%) | catalogued as rs1217756472; called by mutect2, pindel, varscan2
- COASY | c.418T>G p.C140G | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV55899538; called by muse, mutect2, varscan2
- COBL | c.2120C>T p.T707M | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148352652, COSV54351139; called by muse, mutect2, varscan2
- COIL | c.485del p.N162Tfs*47 | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | catalogued as rs769265872; called by mutect2, varscan2
- COL10A1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as COSV54573684; called by muse, mutect2, varscan2
- COL1A2 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs1352712161, COSV51961723; called by muse, mutect2
- COL25A1 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV67653757, COSV67654119; called by muse, mutect2, varscan2
- COL4A1 | c.2806G>T p.G936C | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65428386; called by muse, mutect2, varscan2
- COL5A1 | c.2488del p.X830_splice | Splice Site (DEL) | VAF 13/97 reads (13%) | catalogued as COSV65672780; called by mutect2, pindel, varscan2
- COL9A1 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV61834916; called by muse, mutect2, varscan2
- COMP | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV55875543; called by muse, mutect2
- CORO7 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.258); catalogued as COSV52032054; called by muse, mutect2, varscan2
- CPS1 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766970243, COSV51816792; called by muse, mutect2, varscan2
- CPXM2 | c.904T>C p.Y302H | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV53865975; called by muse, mutect2, varscan2
- CR1L | c.349T>A p.S117T | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1273973330, COSV54328733; called by muse, mutect2, varscan2
- CSMD2 | c.3773G>A p.R1258Q | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs906640660, COSV53932581; called by muse, mutect2, varscan2
- CSNK1G2 | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV55338340; called by muse, mutect2
- CSRNP3 | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV58781915; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTNND1 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV62384792; called by muse, mutect2, varscan2
- CUX1 | c.1289dup p.P431Sfs*16 | Frame Shift Ins (INS) | VAF 24/175 reads (14%) | catalogued as rs782381199; called by mutect2, varscan2
- CYFIP2 | c.265T>G p.C89G | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV59044606; called by muse, mutect2, varscan2
- CYP4F11 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs765657481, COSV56128224, COSV56129477; called by muse, mutect2, varscan2
- CYP4F3 | c.575T>C p.F192S | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV55411668; called by muse, mutect2
- DAAM1 | c.2268G>T p.K756N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV62837892; called by muse, mutect2
- DARS1 | c.286C>A p.H96N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV51539884; called by muse, mutect2
- DCC | c.3847C>A p.P1283T | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71435358; called by muse, mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX54 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs919120286, COSV58374848; called by muse, mutect2, varscan2
- DECR2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777162278, COSV54795320; called by muse, mutect2, varscan2
- DEF8 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); catalogued as rs200129378, COSV51920313; called by muse, mutect2, varscan2
- DEFB114 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.012); catalogued as rs1240354503, COSV59037942, COSV59037991; called by muse, mutect2, varscan2
- DENND3 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs201075864, COSV99370390; called by muse, mutect2
- DENND4B | c.2995G>A p.D999N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1396440625, COSV100768848; called by muse, mutect2
- DEPDC5 | c.2614C>A p.P872T (on ENST00000400246; = p.P941T on NM_014662.5) | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56703392; called by muse, mutect2, varscan2
- DEPP1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.027); catalogued as COSV53574662; called by muse, mutect2, varscan2
- DGCR8 | c.2099del p.R700Lfs*16 | Frame Shift Del (DEL) | VAF 28/191 reads (15%) | catalogued as COSV52814853; called by mutect2, pindel, varscan2
- DGKK | c.2570T>C p.V857A | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65708555; called by muse, mutect2, varscan2
- DHX9 | c.3763dup p.A1255Gfs*27 | Frame Shift Ins (INS) | VAF 14/89 reads (16%) | catalogued as rs775120310; called by mutect2, pindel, varscan2
- DIO2 | c.380A>C p.N127T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70445696; called by muse, mutect2
- DIPK2A | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59857884; called by muse, mutect2, varscan2
- DISC1 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs148111679, CM080195, COSV54407026; called by muse, mutect2, varscan2
- DISP2 | c.1216A>G p.S406G | Missense Mutation (SNP) | VAF 92/486 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as COSV51129180; called by muse, mutect2, varscan2
- DISP2 | c.1448A>G p.H483R | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV51129239; called by muse, mutect2
- DISP3 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.616); catalogued as rs751063533, COSV53821120; called by muse, mutect2, varscan2
- DLG3 | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV52084786; called by muse, mutect2, varscan2
- DLK2 | c.538A>T p.M180L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as COSV55090812; called by muse, mutect2, varscan2
- DMC1 | c.421+1G>A p.X141_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | catalogued as COSV53259873; called by muse, mutect2, varscan2
- DMD | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs398123911, COSV63733958; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- DMXL1 | c.8105A>G p.D2702G | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.352); catalogued as rs772215639, COSV60716320; called by muse, mutect2, varscan2
- DMXL2 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV51850461; called by muse, mutect2, varscan2
- DNAH10 | c.368_369del p.K123Rfs*50 (on ENST00000409039; = p.K62Rfs*50 on NM_207437.3) | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs1305001640; called by mutect2, pindel, varscan2
- DNAH10 | c.902C>T p.A301V (on ENST00000409039; = p.A240V on NM_207437.3) | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV68996927; called by muse, mutect2, varscan2
- DNAH10 | c.5501G>A p.R1834Q (on ENST00000409039; = p.R1773Q on NM_207437.3) | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs916125970, COSV68989405; called by muse, mutect2, varscan2
- DNAH17 | c.6676A>G p.T2226A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101103175; called by muse, mutect2, varscan2
- DNAH2 | c.5975G>A p.R1992H | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754623153, COSV66722375; called by muse, mutect2, varscan2
- DNAH3 | c.8411T>A p.I2804N | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54534688; called by muse, mutect2, varscan2
- DNAH5 | c.10553T>C p.V3518A | Missense Mutation (SNP) | VAF 31/337 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV54238529; called by muse, mutect2
- DNAH9 | c.6215G>A p.R2072H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs377657649; called by muse, mutect2, varscan2
- DNAH9 | c.11897A>C p.K3966T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52360470; called by muse, mutect2, varscan2
- DNAJC14 | c.1312C>G p.P438A | Missense Mutation (SNP) | VAF 90/340 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV57913619; called by muse, mutect2, varscan2
- DNMT3B | c.2086T>C p.F696L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52420405; called by muse, mutect2, varscan2
- DNPH1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV52731211; called by muse, mutect2, varscan2
- DOLK | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs982668501, COSV58281477; called by muse, mutect2, varscan2
- DOP1A | c.3659C>T p.S1220F | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV52713419; called by muse, mutect2, varscan2
- DOT1L | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV67111518; called by muse, mutect2
- DSEL | c.3078dup p.Q1027Sfs*28 | Frame Shift Ins (INS) | VAF 26/184 reads (14%) | catalogued as rs762694026; called by mutect2, varscan2
- DSP | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65793964; called by muse, mutect2, varscan2
- DST | c.4496del p.L1499Wfs*8 (on ENST00000361203 / NM_001374722.1; = p.L1173Wfs*8 on NM_015548.5) | Frame Shift Del (DEL) | VAF 7/83 reads (8%) | catalogued as rs35805169; called by mutect2, pindel
- DUOX2 | c.3257C>T p.T1086M | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs201362841, COSV66533122; called by muse, mutect2, varscan2
- DYNC2H1 | c.12011G>A p.R4004H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779647272, COSV62099714; called by muse, mutect2, varscan2
- DYNC2H1 | c.12227T>C p.I4076T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV62099720; called by muse, mutect2, varscan2
- DYNLRB2 | c.78A>C p.E26D | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV58416588; called by muse, mutect2, varscan2
- DYSF | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50448634, COSV50474723; called by muse, mutect2, varscan2
- ECT2 | c.2365C>T p.R789* (on ENST00000392692 / NM_001349098.2; = p.R758* on NM_018098.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | catalogued as rs1291724943, COSV51691249; called by muse, mutect2, varscan2
- EED | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.245); catalogued as COSV54556800; called by muse, mutect2, varscan2
- EEF2 | c.2368G>A p.V790I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58580078; called by muse, mutect2, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs760813779; called by mutect2, varscan2
- EGR2 | c.1253A>C p.K418T | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV54347655; called by muse, mutect2, varscan2
- EIF1AD | c.85A>G p.R29G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV56463891; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 28/164 reads (17%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF3A | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 81/405 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64961245; called by muse, mutect2, varscan2
- EIF3D | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771870770, COSV53402599; called by muse, mutect2, varscan2
- ELF4 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs1471972731, COSV57451893; called by muse, mutect2, varscan2
- ELOVL2 | c.529A>G p.S177G | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61156148; called by muse, mutect2
- ELP6 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758926474, COSV56132106; called by muse, mutect2, varscan2
- EMC1 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV64346141; called by muse, mutect2, varscan2
- EPB41L3 | c.3213A>T p.K1071N | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59448617, COSV59460416; called by muse, mutect2, varscan2
- EPHA1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.12); catalogued as rs776947009, COSV51973162; called by muse, mutect2
- EPHB2 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65864068; called by muse, mutect2, varscan2
- EPRS1 | c.519A>C p.K173N | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65100213; called by muse, varscan2
- ERBB3 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs758743468, COSV57258067; called by muse, mutect2, varscan2
- ERICH1 | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs778339168, COSV50639368; called by muse, mutect2, varscan2
- ESCO2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767123113, COSV59414087; called by muse, mutect2, varscan2
- ESRP1 | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64411223; called by muse, mutect2, varscan2
- ESYT3 | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538046539, COSV67440793; called by muse, mutect2, varscan2
- EXOSC4 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV60156111; called by muse, mutect2, varscan2
- EXTL1 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs1436408859, COSV65337944; called by muse, mutect2, varscan2
- F2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1423659542, COSV61315682; called by muse, mutect2, varscan2
- FAAP100 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV59886487; called by muse, mutect2, varscan2
- FAAP100 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV59886497; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | catalogued as rs766589051; called by pindel, varscan2
- FAM111B | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as COSV59112668; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM160A2 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56412891; called by muse, mutect2, varscan2
- FAM234B | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV52195842; called by muse, mutect2, varscan2
- FAM47A | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.344); catalogued as rs750698635, COSV60496289; called by muse, mutect2
- FAM47C | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 34/224 reads (15%) | catalogued as COSV63728482, COSV63728983; called by muse, mutect2, varscan2
- FAM47C | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.034); catalogued as rs1345549703, COSV63728492; called by muse, varscan2
- FAM71C | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100175842, COSV60943493; called by muse, mutect2, varscan2
- FAM71E1 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs770665688, COSV58542709; called by muse, mutect2, varscan2
- FAM78B | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs746434862, COSV57975715; called by muse, mutect2, varscan2
- FAN1 | c.2285T>C p.F762S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV62951271; called by muse, mutect2, varscan2
- FAT3 | c.7784A>G p.D2595G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53141226; called by muse, mutect2, varscan2
- FAXC | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67602750; called by muse, mutect2, varscan2
- FBN1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs752010116, CM154799, COSV57312825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.7560del p.Y2521Mfs*90 | Frame Shift Del (DEL) | VAF 24/238 reads (10%) | catalogued as COSV52526371; called by mutect2, pindel, varscan2
- FBXL14 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV59337011; called by muse, mutect2, varscan2
- FBXO15 | c.628T>C p.Y210H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54046894; called by muse, varscan2
- FBXO24 | c.1406C>A p.A469D (on ENST00000241071 / NM_033506.3; = p.A507D on NM_012172.5) | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV53827751; called by muse, mutect2, varscan2
- FBXO31 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1342616722, COSV61149789; called by muse, mutect2, varscan2
- FCGR1A | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV100977307; called by muse, mutect2, varscan2
- FER1L5 | c.5647C>T p.R1883W (on ENST00000623019; = p.R1847W on NM_001293083.2) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs895822949, COSV99383558; called by muse, mutect2, varscan2
- FH | c.983T>C p.M328T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV63818564; called by muse, mutect2, varscan2
- FHOD3 | c.2093G>T p.G698V (on ENST00000359247 / NM_001281739.3; = p.G715V on NM_025135.5) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.915); catalogued as COSV57179968; called by muse, mutect2, varscan2
- FIGN | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs977916754, COSV60769295; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/157 reads (15%) | catalogued as COSV58769165; called by mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs774060142; called by mutect2, varscan2
- FLG | c.11062C>T p.H3688Y | Missense Mutation (SNP) | VAF 66/444 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); catalogued as COSV100911972, COSV64240363; called by muse, mutect2, varscan2
- FMN2 | c.2357C>A p.S786Y | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs201048870, COSV60420095, COSV60440247; called by muse, mutect2, varscan2
- FNDC3B | c.3165dup p.T1056Hfs*16 | Frame Shift Ins (INS) | VAF 13/114 reads (11%) | catalogued as rs769012096; called by mutect2, varscan2
- FNTB | c.709G>T p.G237C | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55762716; called by muse, mutect2, varscan2
- FO393400.1 | c.217A>T p.K73* | Nonsense Mutation (SNP) | VAF 24/129 reads (19%) | catalogued as COSV54070729; called by muse, mutect2, varscan2
- FOXC2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57444031, COSV57444918; called by muse, varscan2
- FOXD3 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs145695569; called by muse, mutect2, varscan2
- FRMD8 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770076651, COSV58213169, COSV58214582; called by muse, mutect2, varscan2
- FRMPD3 | c.2339A>C p.H780P | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs756327086, COSV99346871; called by muse, mutect2, varscan2
- FRY | c.7949T>C p.F2650S | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV66573986; called by muse, mutect2, varscan2
- FSHR | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV58628454; called by mutect2, varscan2
- FZD10 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs770701893, COSV57472020; called by muse, mutect2, varscan2
- FZD4 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV72294555; called by muse, mutect2, varscan2
- GAK | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58506814; called by muse, mutect2
- GALE | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52526623; called by muse, mutect2, varscan2
- GALM | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV55372781; called by muse, mutect2, varscan2
- GALNT16 | c.956del p.G319Efs*83 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | catalogued as rs763094427; called by mutect2, pindel, varscan2
- GALR1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV55318099; called by muse, mutect2, varscan2
- GARS1 | c.941T>G p.F314C | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV66828808; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | catalogued as rs758551787; called by mutect2, varscan2
- GAS1 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV53927517; called by muse, mutect2, varscan2
- GCC2 | c.698del p.N233Ifs*12 | Frame Shift Del (DEL) | VAF 38/218 reads (17%) | catalogued as rs755348339; called by mutect2, varscan2
- GDF2 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs782560993; called by muse, mutect2, varscan2
- GGT5 | c.280T>A p.F94I | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV54071282; called by muse, mutect2, varscan2
- GID4 | c.539T>A p.I180N | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1192460626, COSV52009481; called by muse, mutect2, varscan2
- GIGYF2 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1297435659, COSV65250074; called by muse, mutect2, varscan2
- GJD2 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.339); catalogued as rs1354116514; called by mutect2, varscan2
- GLT8D1 | c.238dup p.A80Gfs*37 | Frame Shift Ins (INS) | VAF 24/156 reads (15%) | catalogued as rs754869681; called by mutect2, varscan2
- GLTP | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV59173236; called by muse, mutect2, varscan2
- GLUD2 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV60152471; called by muse, mutect2, varscan2
- GNAO1 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV52616978; called by muse, mutect2, varscan2
- GNG12 | c.202dup p.T68Nfs*9 | Frame Shift Ins (INS) | VAF 22/182 reads (12%) | catalogued as rs1022402829; called by mutect2, varscan2
- GOLGA2 | c.2884C>T p.R962W | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs141666208; called by muse, mutect2, varscan2
- GOLGA2 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.356); catalogued as rs185837255, COSV57853843; called by muse, mutect2, varscan2
- GPANK1 | c.800dup p.W268Lfs*12 | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | catalogued as rs765697080; called by mutect2, varscan2
- GPATCH8 | c.2659C>T p.R887C | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.635); catalogued as rs771690850, COSV59196090; called by muse, mutect2, varscan2
- GPLD1 | c.2128A>C p.S710R | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV57759286; called by muse, mutect2, varscan2
- GPR101 | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV53239577; called by muse, mutect2, varscan2
- GPR156 | c.1154G>T p.R385M | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV59941189; called by muse, mutect2, varscan2
- GPR50 | c.727T>G p.F243V | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.399); catalogued as COSV54440855; called by muse, mutect2, varscan2
- GPR6 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51572726; called by muse, mutect2, varscan2
- GPT | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs751740696, COSV52953907; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 32/183 reads (17%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN3B | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as rs747783907, COSV52259285; called by muse, mutect2, varscan2
- GRK2 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57951825; called by muse, mutect2, varscan2
- GRK6 | c.1699G>A p.D567N (on ENST00000355472 / NM_001004106.3; = p.A567= on NM_002082.3) | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs748162611, COSV62683367; called by muse, mutect2, varscan2
- GRM8 | c.2524A>T p.I842F | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV58824455; called by muse, mutect2, varscan2
- GSPT2 | c.632A>C p.H211P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61214681; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs781842329, COSV56088897; called by muse, mutect2, varscan2
- GUK1 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs368698841, COSV57157038; called by muse, mutect2, varscan2
- GYG1 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1004038883, COSV99936928; called by muse, mutect2, varscan2
- H2BW1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs200090293, COSV54220759; called by muse, mutect2, varscan2
- HACD4 | c.689del p.K230Rfs*45 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | catalogued as rs768797944; called by mutect2, varscan2
- HAL | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54118928; called by muse, mutect2, varscan2
- HAPLN4 | c.705del p.T236Pfs*43 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as COSV52270379; called by mutect2, pindel, varscan2
- HARS1 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.029); catalogued as rs192923161, COSV56905826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAT1 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV51364054; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs748396956; called by mutect2, varscan2
- HAVCR1 | c.441C>A p.S147R | Missense Mutation (SNP) | VAF 106/742 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV59401489; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 36/251 reads (14%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel, varscan2
- HDLBP | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 14/143 reads (10%) | catalogued as rs1214801603, COSV60492784; called by muse, mutect2, varscan2
- HDX | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV52979520; called by muse, mutect2, varscan2
- HECTD4 | c.1925T>G p.I642S | Missense Mutation (SNP) | VAF 10/299 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV61180478; called by muse, mutect2
- HERC2 | c.10312G>A p.D3438N | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.2); catalogued as rs763806394, COSV55335468; called by muse, mutect2, varscan2
- HIF3A | c.1574G>A p.R525Q (on ENST00000377670 / NM_152795.4; = p.R456Q on NM_022462.4) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs142248233; called by muse, mutect2, varscan2
- HK2 | c.2473G>A p.V825M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as rs898229537, COSV51877127; called by muse, mutect2, varscan2
- HLA-B | c.626dup p.T211Dfs*10 | Frame Shift Ins (INS) | VAF 46/292 reads (16%) | catalogued as rs748204482, COSV69520417; called by mutect2, pindel, varscan2
- HMCN1 | c.6617T>G p.L2206R | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54917520; called by muse, mutect2, varscan2
- HMGB3 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1437497703, COSV57486755; called by muse, mutect2, varscan2
- HOXA3 | c.904dup p.Q302Pfs*42 | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | catalogued as rs761726531; called by mutect2, varscan2
- HOXA6 | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV56074085; called by muse, mutect2, varscan2
- HOXB3 | c.773del p.G258Afs*19 | Frame Shift Del (DEL) | VAF 33/240 reads (14%) | catalogued as COSV57488114; called by mutect2, pindel, varscan2
- HSF4 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.433); catalogued as COSV50458176; called by muse, mutect2, varscan2
- HSPA12B | c.2014A>G p.S672G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.138); catalogued as COSV53924692; called by muse, mutect2, varscan2
- HSPBAP1 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.101); catalogued as COSV60242959; called by muse, mutect2, varscan2
- HSPBP1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.652); catalogued as rs1308201338, COSV55334733; called by muse, mutect2, varscan2
- HSPH1 | c.2377A>G p.N793D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60712476; called by muse, mutect2, varscan2
- IER5L | c.1213T>A p.*405Kext*52 | Nonstop Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV65262716; called by muse, varscan2
- IFNAR1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 26/159 reads (16%) | catalogued as COSV54252606, COSV54253138; called by muse, mutect2, varscan2
- IFRD1 | c.916dup p.Y306Lfs*2 | Frame Shift Ins (INS) | VAF 18/94 reads (19%) | catalogued as rs979653918; called by mutect2, varscan2
- IGFBP1 | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV51875072; called by muse, mutect2, varscan2
- IGHG1 | c.50G>C p.S17T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs372902680; called by muse, varscan2
- IL12B | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs767350741, COSV51455524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL16 | c.1136T>C p.I379T | Missense Mutation (SNP) | VAF 65/387 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV57265907; called by muse, mutect2, varscan2
- IL25 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs767350854, COSV59306867; called by muse, mutect2, varscan2
- IL36RN | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV61010770; called by muse, mutect2, varscan2
- INSM1 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59605076; called by muse, mutect2, varscan2
- INSR | c.4100G>A p.G1367D | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57167011; called by muse, mutect2, varscan2
- INTS6L | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66085149; called by muse, mutect2, varscan2
- IPO8 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377410854, COSV56243447; called by muse, mutect2, varscan2
- IQSEC1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as rs899865181, COSV56225937; called by muse, mutect2, varscan2
- IQSEC1 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as rs748215013, COSV56225958; called by muse, mutect2, varscan2
- IQSEC2 | c.1089G>A p.M363I (on ENST00000642864 / NM_001111125.3; = p.M158I on NM_015075.2) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64726784; called by muse, mutect2, varscan2
- IRF3 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.339); catalogued as rs369809017, COSV55863773; called by muse, mutect2, varscan2
- IRF6 | c.1368del p.S457Afs*34 | Frame Shift Del (DEL) | VAF 21/134 reads (16%) | catalogued as rs1553247577, CD092416; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IRS1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1372054385, COSV59337994; called by muse, mutect2, varscan2
- IRX5 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 54/342 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.286); catalogued as COSV58059431; called by muse, mutect2, varscan2
- ISYNA1 | c.416-3del | Splice Region (DEL) | VAF 10/38 reads (26%) | catalogued as rs764100802; called by mutect2, pindel, varscan2
- ITGA3 | c.2774C>T p.T925I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV50321137; called by muse, mutect2, varscan2
- ITGA7 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV57697713; called by muse, mutect2, varscan2
- ITGAD | c.2440A>G p.T814A | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV66758861; called by muse, mutect2, varscan2
- ITGB1 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs201228879; called by muse, mutect2, varscan2
- ITPR1 | c.4745G>A p.R1582H (on ENST00000354582; = p.R1567H on NM_002222.7) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs569597087, COSV56986194; called by muse, mutect2, varscan2
- ITPRID2 | c.3136G>A p.A1046T | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs774758622, COSV57470705; called by muse, mutect2, varscan2
- JAZF1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.059); catalogued as COSV52241108; called by muse, mutect2, varscan2
- JCHAIN | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs377277594; called by muse, mutect2, varscan2
- KAT6A | c.4709A>T p.D1570V | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55908639; called by muse, mutect2, varscan2
- KCNA3 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63902122; called by muse, mutect2, varscan2
- KCNA6 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.038); catalogued as COSV54976367; called by muse, mutect2, varscan2
- KCNC4 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV63926080; called by muse, mutect2
- KCNF1 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs772769148, COSV54464458; called by muse, mutect2
- KCNH8 | c.2836C>G p.Q946E | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV60469644; called by muse, varscan2
- KCNH8 | c.2846T>G p.L949R | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.352); catalogued as COSV60469649; called by muse, varscan2
- KCNJ15 | c.464T>C p.L155S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60811444; called by muse, mutect2, varscan2
- KCNMA1 | c.3296G>A p.R1099H (on ENST00000286628 / NM_001161352.2; = p.R1041H on NM_002247.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs768399208, COSV54265081; called by muse, mutect2, varscan2
- KCNMA1 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as COSV54236058; called by muse, mutect2, varscan2
- KCNQ2 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs773083197, COSV60434936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNT1 | c.1223A>G p.Q408R (on ENST00000488444; = p.Q427R on NM_020822.3) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV53705673; called by muse, mutect2, varscan2
- KCNT2 | c.2136del p.A713Pfs*8 | Frame Shift Del (DEL) | VAF 15/144 reads (10%) | catalogued as COSV99652693; called by mutect2, pindel, varscan2
- KDM5A | c.1406C>A p.P469Q | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66990464, COSV66993985; called by muse, mutect2
- KDM5B | c.4329del p.K1444Rfs*3 | Frame Shift Del (DEL) | VAF 58/385 reads (15%) | catalogued as COSV52512917; called by mutect2, pindel, varscan2
- KDM5C | c.4426G>A p.E1476K | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.138); catalogued as COSV64766781; called by muse, mutect2, varscan2
- KDR | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55769795, COSV55770193; called by muse, mutect2, varscan2
- KHDRBS2 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55471470; called by muse, mutect2
- KIAA0895L | c.1323G>A p.M441I | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV51783634; called by muse, mutect2, varscan2
- KIAA1614 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs374184068; called by muse, mutect2, varscan2
- KIF13A | c.3345dup p.V1116Sfs*4 | Frame Shift Ins (INS) | VAF 30/158 reads (19%) | catalogued as rs1346755993; called by mutect2, varscan2
- KIF15 | c.3909G>T p.Q1303H | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58162765; called by muse, mutect2, varscan2
- KIF21A | c.2471G>A p.R824H (on ENST00000361418 / NM_001378440.1; = p.R811H on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs558002876, COSV62774467; called by muse, mutect2, varscan2
- KLF10 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53436044, COSV53436569; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs756907493; called by mutect2, pindel, varscan2
- KLHL23 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs751896737, COSV55868382; called by muse, mutect2, varscan2
- KLHL28 | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.994); catalogued as COSV61888762; called by muse, mutect2, varscan2
- KLHL34 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV101069979; called by muse, mutect2
- KLHL38 | c.1170del p.I391Lfs*38 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs1351258817; called by mutect2, varscan2
- KLK11 | c.318G>T p.Q106H (on ENST00000594768 / NM_144947.3; = p.Q74H on NM_006853.3) | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV51577991; called by muse, mutect2, varscan2
- KMT2B | c.7121del p.P2374Qfs*65 | Frame Shift Del (DEL) | VAF 11/114 reads (10%) | catalogued as COSV55860799; called by mutect2, pindel
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 33/241 reads (14%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KMT2C | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.265); catalogued as COSV51466362; called by muse, mutect2, varscan2
- KRI1 | c.1937C>A p.P646H | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as COSV57265268; called by muse, mutect2, varscan2
- KRT4 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as rs1217672254, COSV53408581; called by muse, mutect2
- KRT6A | c.1660A>T p.T554S | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58106453; called by muse, mutect2, varscan2
- KRT81 | c.851A>G p.D284G | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs369316032; called by muse, mutect2, varscan2
- KRTAP26-1 | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 66/472 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV62128521, COSV62129061; called by muse, mutect2, varscan2
- L1CAM | c.2239del p.Q747Rfs*104 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs782198738, CM1514439; called by mutect2, pindel, varscan2
- L3MBTL4 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV53130984; called by muse, mutect2
- LATS2 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as rs778627422, COSV66877562; called by muse, mutect2, varscan2
- LCE1D | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | PolyPhen benign (0.007); catalogued as rs767262622, COSV58271283; called by mutect2, varscan2
- LCE1E | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs753898960, COSV64219939; called by muse, varscan2
- LEMD3 | c.2280A>G p.I760M | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV57649550; called by muse, mutect2, varscan2
- LHPP | c.468-2A>G p.X156_splice | Splice Site (SNP) | VAF 12/372 reads (3%) | catalogued as COSV64330262; called by muse, mutect2
- LIFR | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.857); catalogued as rs781727104, COSV54685260; ClinVar: uncertain significance; called by muse, mutect2
- LILRA2 | c.1452A>G p.*484Wext*29 (on ENST00000391738 / NM_001130917.3; = p.*467Wext*29 on NM_006866.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV52194079; called by muse, mutect2, varscan2
- LINGO2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs778347323, COSV58061692; called by muse, mutect2, varscan2
- LMNB2 | c.1463T>C p.L488P | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57589273; called by muse, mutect2, varscan2
- LMOD3 | c.1256T>C p.M419T | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as COSV70456366; called by muse, mutect2, varscan2
- LMX1B | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.212); catalogued as COSV62740801; called by muse, varscan2
- LMX1B | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62740809; called by muse, varscan2
- LORICRIN | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | PolyPhen possibly damaging (0.632); catalogued as rs1445161170, COSV64201597; called by muse, mutect2, varscan2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 31/217 reads (14%) | catalogued as rs762083435; called by mutect2, varscan2
- LRP1 | c.5996G>A p.R1999H | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766366256, COSV54500784; called by muse, mutect2, varscan2
- LRP2 | c.10199A>G p.H3400R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV55562182; called by muse, mutect2, varscan2
- LRRC10 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs143606238; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 30/116 reads (26%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC36 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as rs754545646, COSV52080701; called by muse, mutect2, varscan2
- LRRC45 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752338494, COSV60712223; called by muse, mutect2, varscan2
- LRRC4B | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.122); catalogued as rs748276107, COSV65350307; called by mutect2, varscan2
- LRRC75B | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 74/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258091949, COSV50640167, COSV50642212; called by muse, mutect2, varscan2
- LRRCC1 | c.93A>C p.K31N | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as COSV64484218, COSV64484346; called by muse, mutect2, varscan2
- LSG1 | c.1945del p.S649Vfs*41 | Frame Shift Del (DEL) | VAF 37/223 reads (17%) | catalogued as rs753137702; called by mutect2, pindel, varscan2
- LSG1 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760507246, COSV54571402; called by muse, mutect2, varscan2
- LTBP2 | c.5251G>A p.V1751M | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149242944; called by muse, mutect2, varscan2
- LYZL2 | c.556G>A p.D186N (on ENST00000375318; = p.D140N on NM_183058.3) | Missense Mutation (SNP) | VAF 87/609 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs771450870, COSV64684648; called by muse, mutect2, varscan2
- MACC1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs769884185, COSV60544593; called by muse, mutect2, varscan2
- MACF1 | c.19169T>C p.L6390P (on ENST00000372915; = p.L4435P on NM_012090.5) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | catalogued as COSV57131622; called by muse, mutect2, varscan2
- MAGEC1 | c.2242T>A p.S748T | Missense Mutation (SNP) | VAF 78/541 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.307); catalogued as COSV53576841; called by muse, mutect2, varscan2
- MAGEE1 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV63910001; called by muse, mutect2
- MAGI2 | c.2259T>G p.Y753* | Nonsense Mutation (SNP) | VAF 39/185 reads (21%) | catalogued as COSV62679052; called by muse, mutect2, varscan2
- MAGI3 | c.3919A>C p.K1307Q | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV56839916; called by muse, mutect2, varscan2
- MAN1A2 | c.1234T>A p.S412T | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV62979545; called by muse, mutect2, varscan2
- MAN2B2 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs148186055, COSV53454931; called by muse, mutect2, varscan2
- MAP1S | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs965878171, COSV60723533; called by muse, mutect2, varscan2
- MAP3K19 | c.3780G>T p.M1260I | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59640512; called by muse, mutect2
- MARCKS | c.980dup p.A328Sfs*14 | Frame Shift Ins (INS) | VAF 27/169 reads (16%) | catalogued as rs770972906; called by mutect2, varscan2
- MARF1 | c.2770G>A p.V924I | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV60025958; called by muse, mutect2, varscan2
- MATR3 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.785); catalogued as COSV63078334; called by muse, mutect2, varscan2
- MBNL1 | c.566A>G p.Q189R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV56832009; called by muse, mutect2, varscan2
- MBP | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV62829864; called by muse, mutect2, varscan2
- MDN1 | c.4844T>C p.M1615T | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV65524989; called by muse, mutect2, varscan2
- MED12L | c.5162G>A p.R1721H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as rs375229306; called by muse, mutect2, varscan2
- MED13 | c.4673T>C p.F1558S | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV67265189; called by muse, mutect2, varscan2
- MEOX2 | c.489C>A p.S163R | Missense Mutation (SNP) | VAF 70/384 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.086); catalogued as COSV56292252; called by muse, mutect2, varscan2
- MEP1A | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57921158; called by muse, mutect2, varscan2
- METTL4 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99859879; called by muse, mutect2
- MIA2 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV54484854; called by muse, mutect2, varscan2
- MICAL2 | c.3323G>A p.G1108D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV56322790; called by muse, mutect2, varscan2
- MICAL3 | c.132G>T p.K44N | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV52901042; called by muse, mutect2, varscan2
- MID1 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs780880323, COSV58196723; called by muse, mutect2, varscan2
- MINAR1 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs373965120; called by muse, mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 32/166 reads (19%) | catalogued as rs751180035; called by mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs749903408; called by mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 27/133 reads (20%) | catalogued as rs751465048; called by mutect2, varscan2
- MLLT10 | c.1231del p.V411* | Frame Shift Del (DEL) | VAF 56/392 reads (14%) | catalogued as rs747811015; called by mutect2, varscan2
- MLST8 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57030064; called by muse, mutect2, varscan2
- MMAA | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 51/375 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55580924; called by muse, mutect2, varscan2
- MMP26 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV56173005; called by muse, mutect2, varscan2
- MMP8 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779074177, CM124469, COSV52633508; called by muse, mutect2, varscan2
- MMUT | c.738T>A p.F246L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as rs779433573, COSV51276937; called by muse, mutect2, varscan2
- MNX1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53318177; called by muse, mutect2, varscan2
- MON1A | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs745397828, COSV56561591; called by muse, mutect2, varscan2
- MOSPD1 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66189488; called by muse, varscan2
- MRC2 | c.3428C>T p.P1143L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as rs1002858985, COSV57641862, COSV57645290; called by muse, mutect2
- MRE11 | c.1184T>C p.I395T | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV60578357; called by muse, mutect2, varscan2
- MRPL39 | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as COSV56261393; called by muse, mutect2, varscan2
- MSR1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs746296271, COSV50518716; called by muse, mutect2, varscan2
- MTCL1 | c.2519A>G p.H840R (on ENST00000306329 / NM_001378206.1; = p.H480R on NM_015210.4) | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs764136809, COSV60408590; called by muse, mutect2, varscan2
- MTMR2 | c.1163G>A p.W388* | Nonsense Mutation (SNP) | VAF 20/149 reads (13%) | catalogued as COSV60580800; called by muse, mutect2, varscan2
- MTMR6 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs956599398, COSV67808930; called by muse, mutect2, varscan2
- MTOR | c.6880A>G p.T2294A | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63874675; called by muse, mutect2, varscan2
- MTR | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as rs138695265; called by muse, mutect2
- MTRF1L | c.1091A>G p.K364R | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs1489410443, COSV65873750; called by muse, mutect2
- MXRA5 | c.6526C>A p.P2176T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV54242000, COSV54254940; called by muse, mutect2
- MXRA8 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV58511149; called by muse, mutect2, varscan2
- MYCN | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55259667; called by muse, mutect2, varscan2
- MYD88 | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV57176980; called by muse, mutect2, varscan2
- MYH15 | c.4693C>T p.R1565C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs200741935, COSV56304734; called by muse, mutect2, varscan2
- MYH15 | c.4224A>T p.R1408S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV56314585; called by muse, mutect2
- MYH2 | c.4805C>T p.S1602F | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV55442587; called by muse, mutect2, varscan2
- MYH9 | c.25T>C p.Y9H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as rs1396960700, COSV53389605; called by muse, mutect2, varscan2
- MYL3 | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52767953; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 80/272 reads (29%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO16 | c.5059C>T p.R1687W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1290980109, COSV62754697; called by muse, mutect2, varscan2
- MYO1A | c.1540T>C p.Y514H | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55655722; called by muse, mutect2, varscan2
- MYO9B | c.6065del p.P2022Lfs*31 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as COSV55726714; called by mutect2, pindel, varscan2
- MYOZ1 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV63772276; called by muse, mutect2, varscan2
- MYRF | c.256C>T p.R86C (on ENST00000278836 / NM_001127392.3; = p.R77C on NM_013279.4) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs756028420, COSV53889178; called by mutect2, varscan2
- NAA25 | c.1418A>G p.H473R | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV55706261; called by muse, mutect2, varscan2
- NBR1 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as rs761883172, COSV100357959; called by muse, mutect2, varscan2
- NCAPG2 | c.2992C>T p.H998Y | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51989454; called by muse, mutect2, varscan2
- NCAPG2 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs186888334, COSV51989466; called by muse, mutect2, varscan2
- NCKAP1L | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756906173, COSV53204504, COSV53210746; called by muse, mutect2, varscan2
- NCKAP5 | c.3636T>A p.D1212E | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV58458862; called by muse, mutect2, varscan2
- NCOA1 | c.3260G>A p.G1087D | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1303370324, COSV56048683; called by muse, mutect2, varscan2
- NDNF | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV65634139; called by muse, mutect2, varscan2
- NEFL | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55337649; called by muse, mutect2, varscan2
- NELFE | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs780466374, COSV64812829; called by muse, mutect2, varscan2
- NES | c.2768T>C p.L923P | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV63961787; called by muse, mutect2, varscan2
- NF1 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765848298, COSV62210672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFATC4 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV51606884; called by muse, mutect2, varscan2
- NFKBIB | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs773488851, COSV58004150; called by muse, mutect2, varscan2
- NINL | c.3058G>T p.G1020W | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as COSV53999034; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 24/167 reads (14%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NLRC5 | c.1346del p.P449Lfs*17 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as rs772651939; called by mutect2, pindel, varscan2
- NLRX1 | c.428del p.P143Hfs*81 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | catalogued as rs767102699; called by mutect2, pindel, varscan2
- NMNAT3 | c.627G>T p.L209F (on ENST00000296202 / NM_001320512.1; = p.L172F on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56157389; called by muse, mutect2, varscan2
- NMUR1 | c.978G>T p.W326C | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59403776, COSV59404953; called by muse, mutect2, varscan2
- NOL6 | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV53043528; called by muse, mutect2
- NOX4 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as COSV54458482; called by muse, mutect2, varscan2
- NPY2R | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61528892; called by muse, mutect2, varscan2
- NR6A1 | c.218G>T p.G73V (on ENST00000487099 / NM_033334.4; = p.G69V on NM_001489.5) | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60635283; called by muse, mutect2, varscan2
- NRCAM | c.1219G>A p.D407N (on ENST00000379028 / NM_001371124.1; = p.D401N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.387); catalogued as COSV100695133, COSV61042242; called by muse, mutect2, varscan2
- NRIP1 | c.2462G>A p.R821Q | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.536); catalogued as rs774507180, COSV59658784; called by muse, mutect2, varscan2
- NRK | c.1205A>C p.Q402P | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV54601301; called by muse, mutect2, varscan2
- NSD1 | c.7067C>T p.T2356M | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs780750393, COSV61775750; called by muse, mutect2, varscan2
- NTM | c.927G>C p.M309I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66185600; called by muse, mutect2, varscan2
- NTRK1 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV62326977; called by muse, mutect2, varscan2
- NUP155 | c.3845T>C p.V1282A (on ENST00000231498 / NM_153485.3; = p.V1223A on NM_004298.4) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV51532059; called by muse, mutect2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 20/154 reads (13%) | catalogued as rs758695627; called by mutect2, varscan2
- NUP98 | c.5404C>T p.R1802C (on ENST00000359171 / NM_001365126.1; = p.R1785C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs765252401, COSV51709157; called by muse, mutect2, varscan2
- NUTM2F | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99480323; called by muse, mutect2, varscan2
- NUTM2G | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 29/321 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs371722833; called by muse, mutect2, varscan2
- NXNL2 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | catalogued as COSV65474440, COSV65474599; called by muse, mutect2, varscan2
- NXPE1 | c.816A>T p.E272D (on ENST00000424269; = p.E130D on NM_152315.5) | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52631222; called by muse, mutect2, varscan2
- OBSCN | c.17618G>A p.R5873H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1478495548, COSV52797816; called by muse, mutect2
- OR10V1 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV55699474; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1B1 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs77073101; called by muse, mutect2, varscan2
- OR2A7 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 20/309 reads (6%) | catalogued as COSV71827895; called by muse, mutect2
- OR2G2 | c.68A>G p.Y23C | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV60741275; called by muse, mutect2, varscan2
- OR2G2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs760919741, COSV60739255; called by muse, mutect2, varscan2
- OR2L2 | c.595T>G p.F199V | Missense Mutation (SNP) | VAF 59/355 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV63549022, COSV63556852; called by muse, mutect2, varscan2
- OR2T4 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs199743254, COSV63544206, COSV63544524; called by muse, mutect2, varscan2
- OR51G1 | c.154T>C p.C52R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV58969819; called by muse, mutect2
- OR52E8 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.044); catalogued as rs757590811, COSV66208796; called by muse, mutect2
- OR52M1 | c.176A>C p.Q59P | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV64172319; called by muse, mutect2, varscan2
- OR5A2 | c.404T>A p.V135D | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV57391457; called by muse, mutect2, varscan2
- OR5B12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs139365126; called by muse, mutect2, varscan2
- OR5H1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs190397100; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 42/143 reads (29%) | catalogued as rs746200712; called by mutect2, varscan2
- OVCH1 | c.2737A>C p.S913R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV58965404; called by muse, mutect2, varscan2
- OXCT1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM074399, COSV52173608; called by muse, mutect2
- OXTR | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV57479950; called by muse, mutect2, varscan2
- P3H3 | c.540_542del p.F181del | In Frame Del (DEL) | VAF 96/334 reads (29%) | catalogued as rs781882653; called by pindel, varscan2
- PABPC4 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV63293539; called by muse, mutect2, varscan2
- PABPC5 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV57041909, COSV57043280; called by muse, mutect2, varscan2
- PACS2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs200599760, COSV57655321; called by muse, mutect2, varscan2
- PALD1 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.302); catalogued as COSV54976186; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2423T>G p.L808R (on ENST00000259318 / NM_001136562.3; = p.L1039R on NM_007203.5) | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52179048; called by muse, mutect2, varscan2
- PAQR8 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.927); catalogued as COSV62443126; called by muse, mutect2
- PARD3B | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV100594760; called by muse, mutect2, varscan2
- PARP14 | c.1244del p.N415Mfs*3 | Frame Shift Del (DEL) | VAF 45/303 reads (15%) | catalogued as rs1414616694, COSV71735122; called by mutect2, pindel, varscan2
- PAX9 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV64062003; called by muse, mutect2, varscan2
- PBX2 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV66709132; called by muse, varscan2
- PBX2 | c.130del p.V44Sfs*17 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as rs747720400, COSV66708728; called by pindel, varscan2
- PC | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV58993269; called by muse, mutect2, varscan2
- PCDH10 | c.1240A>C p.T414P | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99994279; called by muse, mutect2, varscan2
- PCDH10 | c.1241C>A p.T414N | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99994282; called by muse, mutect2, varscan2
- PCDH15 | c.983T>A p.V328D | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as COSV57282934; called by muse, varscan2
- PCDHA3 | c.596del p.N199Ifs*2 | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | catalogued as rs782411180, COSV65371489; called by mutect2, varscan2
- PCDHA9 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV100970248, COSV65329311; called by muse, mutect2, varscan2
- PCDHAC2 | c.2527C>A p.L843M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); catalogued as COSV53859419; called by muse, mutect2, varscan2
- PCDHB14 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 55/412 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV53389546; called by muse, mutect2, varscan2
- PCDHB7 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.044); catalogued as rs372965970; called by muse, mutect2, varscan2
- PCDHGB5 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53985026; called by muse, mutect2, varscan2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 12/108 reads (11%) | catalogued as rs772305388; called by mutect2, pindel, varscan2
- PCOLCE2 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs762154075, COSV56000491; called by muse, mutect2, varscan2
- PDE10A | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as rs1403420962, COSV63091276; called by muse, varscan2
- PDE1C | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as COSV58515518, COSV58520064; called by muse, mutect2
- PDGFD | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771113435, COSV56377995, COSV56385131; called by muse, mutect2, varscan2
- PEG3 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV55639586; called by muse, mutect2, varscan2
- PFN3 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV53692132; called by muse, mutect2, varscan2
- PHEX | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV65077112; called by muse, mutect2, varscan2
- PIAS3 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs782552967, COSV100992720, COSV65171729; called by muse, varscan2
- PILRA | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 32/193 reads (17%) | catalogued as COSV52201246; called by muse, mutect2, varscan2
- PKHD1L1 | c.4782G>T p.W1594C | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99058764; called by muse, mutect2, varscan2
- PKN3 | c.1717G>A p.V573I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV52578131; called by muse, mutect2, varscan2
- PKNOX1 | c.1090A>G p.M364V | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs763181221, COSV52337644; called by muse, mutect2, varscan2
- PLA2G4F | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs770482481, COSV51828168; called by muse, mutect2, varscan2
- PLA2G7 | c.799del p.I267* | Frame Shift Del (DEL) | VAF 13/129 reads (10%) | catalogued as rs377632936; called by mutect2, pindel, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 58/314 reads (18%) | catalogued as rs745860467; called by mutect2, varscan2
- PLAUR | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as rs755139842, COSV55389450; called by muse, mutect2, varscan2
- PLCE1 | c.5810G>A p.R1937H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314937548, COSV53360217, COSV53371322; called by muse, mutect2, varscan2
- PLEKHG1 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV62049013; called by muse, mutect2, varscan2
- PLP1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 62/411 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.761); catalogued as rs132630295, CM078425, CM1312266, COSV58277298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA1 | c.3103C>A p.L1035I | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.034); catalogued as COSV52529499; called by muse, mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PNMA3 | c.261dup p.P88Afs*10 | Frame Shift Ins (INS) | VAF 20/134 reads (15%) | catalogued as rs781795278; called by mutect2, varscan2
- PNMA5 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV62625894; called by muse, mutect2, varscan2
- PNPLA4 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 18/178 reads (10%) | catalogued as rs372843326, CM161321, COSV66854267; called by muse, mutect2, varscan2
- PNPLA7 | c.2227C>A p.L743I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV53002221; called by muse, mutect2, varscan2
- PODNL1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.184); catalogued as rs1483316106, COSV54307910; called by muse, mutect2, varscan2
- POFUT2 | c.556A>G p.R186G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.193); catalogued as COSV57959997; called by muse, mutect2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLN | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777069200, COSV67026304; called by muse, mutect2, varscan2
- POLR1D | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57256381; called by muse, mutect2, varscan2
- POLR3B | c.496+1G>A p.X166_splice | Splice Site (SNP) | VAF 17/136 reads (13%) | catalogued as rs1186072780, COSV57281558; called by muse, mutect2, varscan2
- POMT1 | c.1048A>G p.M350V | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100586546; called by muse, mutect2, varscan2
- POU6F1 | c.1541T>C p.V514A | Missense Mutation (SNP) | VAF 49/420 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV61327246; called by muse, mutect2, varscan2
- PPM1E | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1159529040, COSV57575742, COSV57576823; called by muse, mutect2, varscan2
- PPP1R12B | c.2636A>G p.N879S | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51787510; called by muse, mutect2, varscan2
- PPP1R36 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53902958; called by muse, mutect2
- PPRC1 | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV53387010; called by muse, mutect2, varscan2
- PRDM7 | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV57987307; called by muse, mutect2, varscan2
- PRDM8 | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60204189; called by muse, mutect2, varscan2
- PRDM9 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.175); catalogued as COSV57009693; called by muse, mutect2, varscan2
- PRKCA | c.545del p.N182Ifs*2 | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | catalogued as rs773101122; called by mutect2, pindel, varscan2
- PRKCB | c.157T>G p.C53G | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57789000; called by muse, mutect2, varscan2
- PRKCE | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV60323704; called by muse, mutect2, varscan2
- PRKCZ | c.368G>T p.R123M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66069301; called by muse, mutect2
- PROCA1 | c.176-1G>T p.X59_splice (on ENST00000439862 / NM_001366301.1; = p.X31_splice on NM_152465.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 15/103 reads (15%) | catalogued as COSV56387774; called by muse, mutect2, varscan2
- PROKR2 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs761425593, COSV54084959, COSV54084982; called by muse, mutect2
- PRPS2 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV66126459; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 39/250 reads (16%) | catalogued as rs781858060; called by mutect2, varscan2
- PRRX2 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs143523637; called by muse, mutect2, varscan2
- PSMD1 | c.2080A>G p.I694V | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.13); catalogued as COSV58081086; called by muse, mutect2, varscan2
- PSMD3 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52858616, COSV99228116; called by muse, mutect2, varscan2
- PTCHD1 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as COSV65061721; called by muse, mutect2, varscan2
- PTGS1 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753219685, COSV56293178; called by muse, mutect2, varscan2
- PTPN13 | c.855del p.K285Nfs*45 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs754278242; called by mutect2, varscan2
- PTPRO | c.1735A>G p.T579A | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV55515655; called by muse, mutect2
- PXDN | c.3229G>T p.V1077F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99414574; called by muse, mutect2, varscan2
- PXDNL | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1336997230, COSV62478398; called by muse, mutect2, varscan2
- PYGM | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM063080, COSV51221716; called by muse, mutect2, varscan2
- QRFPR | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV57678566; called by muse, mutect2, varscan2
- RAB12 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.192); catalogued as COSV61398860; called by muse, mutect2, varscan2
- RAB43 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs1204549862, COSV100167615; called by muse, mutect2
- RABGAP1L | c.1897C>T p.H633Y | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52309088; called by muse, mutect2, varscan2
- RAD9A | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762431269, COSV57236955; called by muse, mutect2, varscan2
- RAF1 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.132); catalogued as rs865905076, COSV50106255; called by muse, mutect2, varscan2
- RALGPS2 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as rs777726293, COSV61338404; called by muse, mutect2, varscan2
- RANBP6 | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52389259, COSV52390399; called by mutect2, varscan2
- RAPGEF6 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV57250357; called by muse, mutect2, varscan2
- RASGEF1C | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs145725435; called by muse, mutect2, varscan2
- RASIP1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as rs769130629, COSV55806487; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM33 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs745480919, COSV100265524, COSV56629068; called by muse, mutect2, varscan2
- RBM43 | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV58879337; called by muse, mutect2, varscan2
- RBM43 | c.213del p.V72Lfs*13 | Frame Shift Del (DEL) | VAF 34/169 reads (20%) | catalogued as rs746242773; called by mutect2, varscan2
- RBM4B | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs201202684, COSV59497500; called by muse, mutect2, varscan2
- RCOR3 | c.397del p.T133Lfs*7 | Frame Shift Del (DEL) | VAF 25/177 reads (14%) | catalogued as COSV65365594; called by mutect2, pindel, varscan2
- REG3A | c.70G>T p.V24F | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV59410545; called by muse, mutect2, varscan2
- RELN | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs144078760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REM1 | c.100A>C p.S34R | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52429062; called by muse, mutect2, varscan2
- REXO5 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238387602, COSV54471101; called by muse, mutect2, varscan2
- RHO | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV56214068; called by muse, mutect2, varscan2
- RHOBTB2 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.901); catalogued as rs1563292435, COSV52569840; called by muse, mutect2, varscan2
- RIOX2 | c.313T>C p.C105R | Missense Mutation (SNP) | VAF 78/621 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV57724448; called by muse, mutect2, varscan2
- RMC1 | c.1664T>C p.L555P | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52572971; called by muse, mutect2, varscan2
- RMI1 | c.1016T>G p.L339W | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV57936995; called by muse, mutect2, varscan2
- RNASE10 | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs147896742, COSV60517946; called by muse, mutect2, varscan2
- RNASEH2C | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57730112; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF213 | c.2656-1G>T p.X886_splice | Splice Site (SNP) | VAF 14/98 reads (14%) | catalogued as COSV100173838; called by muse, mutect2, varscan2
- RNF213 | c.12304C>T p.R4102C | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs768906078, COSV60402870; called by muse, mutect2, varscan2
- ROBO2 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs751711354, COSV59893559, COSV59899603; called by muse, mutect2, varscan2
- ROBO4 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs140504916, COSV60625838; called by muse, mutect2, varscan2
- ROCK2 | c.412del p.W138Gfs*31 | Frame Shift Del (DEL) | VAF 36/239 reads (15%) | catalogued as rs755738345; called by mutect2, pindel, varscan2
- ROPN1B | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.156); catalogued as rs143434891, COSV52542826; called by muse, mutect2, varscan2
- RP9 | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV51807252; called by muse, mutect2, varscan2
- RPAP1 | c.3678C>A p.H1226Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.157); catalogued as COSV58540829; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL27 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53814992; called by muse, mutect2, varscan2
- RPS5 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52191336; called by muse, mutect2, varscan2
- RPS6KA4 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53704872; called by muse, mutect2, varscan2
- RSPH10B | c.2450T>C p.L817S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV58074537; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs747510098; called by mutect2, varscan2
- RTP4 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.05); catalogued as COSV52018750; called by muse, mutect2, varscan2
- RUBCN | c.2416C>A p.L806I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56369688; called by muse, mutect2
- RYBP | c.364A>G p.N122D | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.038); catalogued as COSV72180782; called by muse, mutect2, varscan2
- RYR2 | c.13823G>A p.R4608Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1553328170, CM148846, COSV63697882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.12014C>A p.P4005Q (on ENST00000389232; = p.P4006Q on NM_001036.6) | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66799928; called by muse, mutect2, varscan2
- SAMD4B | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58752379; called by muse, mutect2, varscan2
- SART3 | c.1532G>A p.R511Q (on ENST00000228284; = p.R493Q on NM_014706.4) | Missense Mutation (SNP) | VAF 45/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57208766; called by muse, mutect2, varscan2
- SBF1 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs768308575, COSV62368934; called by muse, mutect2, varscan2
- SCARF2 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV56733194; called by muse, mutect2, varscan2
- SCFD1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as rs780565371, COSV61725320; called by muse, mutect2, varscan2
- SCN10A | c.4727G>A p.R1576H | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs777606824, COSV71860179; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SCN2A | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV51847985; called by muse, mutect2, varscan2
- SCN2B | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.142); catalogued as COSV54051320; called by muse, mutect2, varscan2
- SEBOX | c.110C>A p.A37E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs201656992, COSV52647483, COSV99412311; called by muse, mutect2, varscan2
- SEC62 | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.185); catalogued as rs1158142648, COSV61261738; called by muse, mutect2, varscan2
- SEL1L | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60921363; called by muse, mutect2, varscan2
- SEMA3A | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54878324; called by muse, mutect2, varscan2
- SEMA6B | c.826del p.R276Afs*11 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | catalogued as rs781437207, COSV56702141, COSV56702780; called by mutect2, pindel, varscan2
- SEPTIN4 | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.029); catalogued as COSV58728499; called by muse, mutect2, varscan2
- SETBP1 | c.2492C>A p.P831Q | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56328982; called by muse, mutect2
- SEZ6L2 | c.1509del p.N504Mfs*69 (on ENST00000308713 / NM_001114099.3; = p.N434Mfs*69 on NM_012410.4) | Frame Shift Del (DEL) | VAF 40/362 reads (11%) | catalogued as COSV100435397; called by mutect2, pindel, varscan2
- SFRP2 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56837362, COSV56838058; called by muse, mutect2, varscan2
717 further variants in this file (380 protein-altering or splice-affecting, 303 silent, 34 other) are not listed here.
